Surgical pathology report (de-identified scan), TCGA case TCGA-HB-A3L4, project TCGA-SARC (Sarcoma), tissue source site University of North Carolina, specimen TCGA-HB-A3L4-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Uterus and cervix, hysterectomy

- Leiomyosarcoma (18 cm), involving lower uterine segment and cervix (see

comment). The tumor contains up to 90 mitotic figures per 10 high power fields.

The tumor is estrogen receptor positive and progesterone receptor positive.

- Benign secretory phase endometrium.

- Adenomyosis and leiomyomata.

B: Ovaries and fallopian tubes, bilateral, removal

- No tumor seen.

- One ovary with hemorrhagic corpus luteum.

- Fallopian tubes with no diagnostic abnormality.

Comment:

Sections of the 18 cm mass involving the LUS and cervix show a high-grade

malignant neoplasm with spindled and focal epithelioid features.

The tumor

shows histologic evidence of smooth muscle differentiation. A mitotic count

reveals up to 90 mitotic figures per 10 high power fields. The tumor

additionally shows significant cytologic atypia and coagulative tumor necrosis.

Immunohistochemical studies show the tumor to be strongly positive for smooth

muscle actin, desmin, estrogen receptor (2-3+, >90%) and progesterone receptor

(2-3+, 70%). The tumor is negative for OSCAR pancytokeratin.

This

immunophenotype supports the diagnosis of leiomyosarcoma.

Intraoperative Consult Diagnosis:

An intraoperative consultation was requested by Dr. in (

FSA1: Uterus and cervix

- Malignant spindle cell neoplasm with necrosis, nuclear pleomorphism and

100-0-3
leiomyosarcoma, NOS 8890/3
Rth Site: lower uterine segment 654.0
CQCF uterus, NOS 655.9
12/19/11

[page 2 of 3]
mitotic activity, favor leiomyosarcoma

Drs. at

Clinical History:

-year-old female with a cervical mass.

Gross Description:

Received are two appropriately labeled containers.

Container A is additionally labeled "uterus and cervix." It contains a 1150 gram uterus and cervix with a large mass originating from the lower segment of the uterus or cervix. The mass measures 18 x 14 x 8 cm. The cut surface is nodular, tan to brown with more fibrous areas and appears focally necrotic. It is predominantly well circumscribed mass. The majority of the mass appears to have a peritoneal lining, but orientation of the uterus in relation to the mass is difficult due to the distortion of the specimen. Sectioning of the remainder of the uterus does not reveal additional masses or nodules.

Block summary:

A1,A2 - cervix and opposing cervix
A3,A4 - grossly uninvolved myometrium and endometrium
A5-A16 - representative sections of tumor

Container B is additionally labeled "right and left ovaries."

The specimen consists of two tissue fragments grossly consistent with bilateral ovaries and fallopian tubes which are otherwise undesignated. The larger ovary measures 2.5 x 2.0 x 2.0 cm with a smooth lobulated white/tan to pink external surface and a cut surface revealing a hemorrhagic appearing corpus luteum. The associated fallopian tube is approximately 4 cm in length with an external

[page 3 of 3]
diameter of 0.6
cm. Representative sections are taken and submitted in blocks B1
and B2.

The second ovary and fallopian tube measures as follows: the
ovary measures 2.3
x 1.5 x 1.3 cm and it has a white/tan and faintly lobulated
smooth external
surface with a fibrous to white benign appearing cut surface.
Associated
fallopian tube measures approximately 3.5 cm in length with an
external diameter
of 0.8 cm. Representative sections are taken and submitted in
blocks B3 and B4.

Source: NCI Genomic Data Commons file c773f5b4-c953-4021-954e-f1aacac0c640 (TCGA-HB-A3L4.5394ACFD-3583-4E61-9BEC-DB0BB1C1B656.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).